TCGA case TCGA-BI-A0VS — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3923a64a-f8d7-4e3e-9218-cee642da21db

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 48.8 years (17,839 days); Year of diagnosis: 2007; Method of diagnosis: Cytology; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 8; Lymphatic invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (20 entries)
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 12 (preoperative): Days to imaging: 12 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Days to follow up: 925 days (2.5 years); Disease response: Tumor Free.
- Days to follow up: 1,735 days (4.8 years); Disease response: Tumor Free.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease; Timepoint: Preoperative.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Parametrium Involvement; Timepoint: Preoperative.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement; Timepoint: Preoperative.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement; Timepoint: Preoperative.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Bladder Involvement; Timepoint: Preoperative.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement; Timepoint: Preoperative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BI-A0VS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-BI-A0VS-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 37; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BI-A0VS-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BI-A0VS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BI-A0VS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 1; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Tobacco smoking history indicator: 2; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymphovascular invasion: Absent.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Diagnostic mri result outcomes: Lymph nodes supraclavicular: Bladder Absent; Lymph nodes supraclavicular: Extra-Pelvic Metastatic Disease Absent; Lymph nodes supraclavicular: Parametrium Absent; Lymph nodes supraclavicular: Paraaortic Nodes Absent; Lymph nodes supraclavicular: Pelvic Nodes Absent; Lymph nodes supraclavicular: Supraclavicular Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Stage record: AJCC clinical tumor stage: Stage IB.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,735 days; disease-specific survival: no event (censored), 1,735 days; disease-free interval: no event (censored), 1,735 days; progression-free interval: no event (censored), 1,735 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BI-A0VS-01A-11D-A10T-01): tumor purity 0.49, ploidy 3.62, whole-genome doublings 1.
